Gene-level copy-number profile of tumor specimen TCGA-AR-A2LM-01A from TCGA case TCGA-AR-A2LM, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 49.4 years (18,053 days).
Specimen TCGA-AR-A2LM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.27925a3c-9258-4c9e-9674-34c744a31eb3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A2LM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1fa01db0-4bfe-4b55-9329-01b1595b5316

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 3,339; copy number 2: 51,968; copy number 3: 1,561; copy number 4: 2,604; copy number 6: 16; copy number 7: 9; copy number 10: 40; copy number 11: 85; copy number 13: 1; copy number 14: 53; copy number 15: 20; copy number 16: 16; copy number 19: 43; copy number 25: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A2LM-01A-11D-A17U-01): tumor purity 0.57, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:73,686,089–75,859,870, 25 genes (within-gene range 0–1): KLF12, AL138713.1, AL159972.1, LINC00402, AL353660.1, RNY1P5, RPL21P108, AL355390.1, LINC00381, AL355390.2, LINC00347, RIOK3P1, RNU6-38P, SSR1P2, CTAGE11P, LINC01078, TBC1D4, AL139230.1, COMMD6, UCHL3, AL137782.1, LMO7-AS1, LMO7, AL137244.1, FAM204CP.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 320 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:19,724,435–29,784,759, 166 genes, copy number 7–25 (within-gene range 2–25) (broad region; genes not listed).
- chr12:30,454,919–32,756,463, 75 genes, copy number 6–11 (broad region; genes not listed).
- chr17:16,666,107–17,617,745, 53 genes, copy number 14: NEK4P2, RNASEH1P2, CCDC144A, AC098850.3, RNU6-405P, RN7SL620P, UPF3AP1, USP32P1, SRP68P1, AC098850.4, AC098850.1, FAM106C, AC022596.1, NOS2P4, KRT16P6, KRT16P2, KRT17P1, KRT17P4, COTL1P1, AC022596.2, AL353996.1, TBC1D27P, TNFRSF13B, AC104024.1, LINC02090, AC104024.2, AC104024.3, AC104024.4, MPRIP, MPRIP-AS1, AC055811.1, RNU6-767P, RN7SL775P, AC055811.4, PLD6, AC055811.2, FLCN, AC055811.3, ACTG1P24, COPS3, NT5M, RPL13P12, AC073621.1, TSEN15P1, Y_RNA, MED9, RASD1, AC020558.6, PEMT, AC020558.2, RNU6-468P, AC020558.1, AC020558.5.
- chr17:20,716,481–21,253,410, 26 genes, copy number 11: AC087499.2, RNFT1P3, HNRNPA1P19, OLA1P2, SCDP1, AC126365.1, AC126365.2, ABHD17AP6, CCDC144NL, AC090774.2, CCDC144NL-AS1, RNU6-1178P, RNASEH1P1, AC090774.1, SPECC1P2, AC107926.1, AC087393.3, AC087393.1, USP22, AC087393.2, LINC01563, DHRS7B, TMEM11, AC087294.1, RN7SL426P, NATD1.

Autosomal genes at a single copy (total copy number 1): 3,339. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
